Somatic mutation profile of tumor specimen TCGA-67-3771-01A (aliquot TCGA-67-3771-01A-01D-1040-01) from TCGA case TCGA-67-3771, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.8 years (28,406 days).
Specimen TCGA-67-3771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb01c35f-7fb6-4fbb-9459-48cd37689ebe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-3771-10A (Blood Derived Normal), aliquot TCGA-67-3771-10A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97d1d1f5-8247-4236-bd77-9ffbe40d345d

The open-access MAF lists 1,183 somatic variants for this specimen: 883 protein-altering or splice-affecting, 269 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 753, Silent 269, Nonsense Mutation 67, Frame Shift Del 34, Splice Site 16, Intron 13, RNA 9, 5'Flank 6, Splice Region 5, Frame Shift Ins 4, In Frame Del 3, 5'UTR 2.

Variants (750 of 1,183; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as rs61748538, CM015069, COSV64671902, COSV64673084; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 14/25 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50262762, COSV50266035; called by muse, mutect2, varscan2
- MAP2K4 | c.891+1G>C p.X297_splice | Splice Site (SNP) | VAF 17/41 reads (41%) | hotspot (GDC flag); catalogued as COSV62255661, COSV62258008, COSV62258724; called by muse, mutect2, varscan2
- TP53 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA9 | c.2918T>A p.I973K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1402042205, COSV60622167; called by muse, mutect2, varscan2
- ABCC3 | c.4093C>G p.Q1365E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV53318685, COSV53326417; called by muse, mutect2, varscan2
- ABCC4 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV65310647; called by muse, mutect2
- ABCC9 | c.3650G>C p.R1217T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs12298510, COSV53965202; called by muse, mutect2, varscan2
- ABCC9 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV53965219; called by muse, mutect2
- ABCG1 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV68251368; called by muse, mutect2, varscan2
- ABL2 | c.2679G>C p.K893N (on ENST00000502732 / NM_007314.4; = p.K878N on NM_005158.5) | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as COSV61011947; called by muse, mutect2, varscan2
- ACADM | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV63719942; called by muse, mutect2, varscan2
- ACBD4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV58851104; called by muse, mutect2, varscan2
- ACP5 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54535982; called by muse, mutect2, varscan2
- ACP5 | c.352T>A p.S118T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.134); catalogued as COSV99520424; called by muse, mutect2, varscan2
- ACSM2A | c.944A>C p.Y315S (on ENST00000219054; = p.Y236S on NM_001308169.2) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54583158; called by muse, mutect2, varscan2
- ACTR8 | c.1055A>G p.H352R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51635538; called by muse, mutect2, varscan2
- ADAM10 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV53049939; called by muse, mutect2, varscan2
- ADAM12 | c.1082A>T p.D361V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900107, COSV64103821; called by muse, mutect2, varscan2
- ADAM17 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV60397996, COSV60398180; called by muse, mutect2
- ADAM29 | c.1736T>G p.I579R | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV100822152; called by muse, mutect2, varscan2
- ADAM7 | c.2143G>T p.G715* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV51536680, COSV51546498; called by muse, mutect2, varscan2
- ADAMTS1 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53169217; called by muse, mutect2
- ADAMTS12 | c.4634C>T p.S1545L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV61257937; called by muse, mutect2, varscan2
- ADAMTS16 | c.2885C>T p.S962L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs769507235, COSV56982212; called by muse, varscan2
- ADAMTS17 | c.869G>C p.R290P | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.941); catalogued as COSV51475361; called by muse, mutect2, varscan2
- ADCY10 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV63239149; called by muse, mutect2, varscan2
- ADGRB3 | c.2161C>G p.P721A | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1242236635, COSV65383789, COSV65387777; called by muse, mutect2, varscan2
- ADGRF4 | c.1933-1G>T p.X645_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV51949947, COSV51950407; called by muse, mutect2, varscan2
- ADNP2 | c.1451C>G p.S484* | Nonsense Mutation (SNP) | VAF 15/102 reads (15%) | catalogued as COSV51537120; called by muse, mutect2, varscan2
- ADRA2A | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54527171; called by muse, mutect2, varscan2
- ADRB3 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as COSV61461607; called by muse, mutect2, varscan2
- AEBP1 | c.1295C>A p.A432E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56256190, COSV56260647; called by muse, mutect2, varscan2
- AHCTF1 | c.1087G>A p.E363K (on ENST00000366508; = p.E337K on NM_015446.5) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV58247297; called by muse, mutect2, varscan2
- AHCYL1 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as COSV63208376; called by muse, mutect2, varscan2
- AHNAK2 | c.2641C>A p.L881I | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1405225809, COSV100317064, COSV60910570, COSV60915598; called by muse, mutect2, varscan2
- ALLC | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as COSV52993554; called by muse, mutect2, varscan2
- AMY2B | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63714412; called by muse, mutect2, varscan2
- ANGPT1 | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52434035; called by muse, mutect2
- ANGPTL6 | c.617C>A p.P206Q | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV53461631, COSV53462268; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6529G>T p.V2177L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.057); catalogued as COSV51842683; called by muse, mutect2, varscan2
- ANKMY1 | c.2425G>T p.E809* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV56031329; called by muse, mutect2, varscan2
- ANKRD29 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52424852; called by muse, mutect2, varscan2
- ANKRD34B | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV58613595; called by muse, varscan2
- ANKRD52 | c.851A>T p.N284I | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57283175, COSV99031712; called by muse, mutect2, varscan2
- ANKRD55 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV61944945; called by muse, mutect2, varscan2
- ANKZF1 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 88/302 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55475792; called by muse, mutect2, varscan2
- ANO5 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61083227; called by muse, mutect2, varscan2
- APEH | c.2187C>G p.H729Q | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56532663; called by muse, mutect2, varscan2
- APOA4 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as rs1352011550, COSV63360187; called by muse, mutect2, varscan2
- APOA5 | c.551C>A p.T184N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as CM1213290, COSV57062636; called by muse, mutect2, varscan2
- APOB | c.4726G>T p.G1576W | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51927827; called by muse, varscan2
- ARHGAP12 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV60962116; called by muse, mutect2, varscan2
- ARHGEF37 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61368214; called by muse, mutect2, varscan2
- ARID1A | c.3219del p.W1073Cfs*20 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV104411790; called by mutect2, pindel, varscan2
- ARMT1 | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV66178428; called by muse, mutect2, varscan2
- ARPP21 | c.1609C>A p.P537T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV51793997; called by muse, mutect2
- ARRDC1 | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as rs767794828, COSV58372060; called by muse, mutect2, varscan2
- ASB8 | c.543C>A p.N181K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56656437; called by muse, mutect2, varscan2
- ASB9 | c.536A>G p.Q179R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV66851438; called by muse, mutect2, varscan2
- ASTN1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.127); catalogued as COSV56064290; called by muse, mutect2, varscan2
- ASXL1 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60104996, COSV60118368; called by muse, mutect2, varscan2
- ATG101 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as rs1199689526, COSV61085000; called by muse, mutect2, varscan2
- ATP4A | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs761748330, COSV52866616; called by muse, mutect2, varscan2
- ATP5F1A | c.635G>C p.G212A | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV56359770; called by muse, mutect2, varscan2
- ATP6V1H | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV62217452; called by muse, mutect2, varscan2
- ATP7B | c.3919G>T p.V1307L | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54436306; called by muse, mutect2, varscan2
- ATP8A2 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54942662; called by muse, mutect2, varscan2
- ATRN | c.1392C>G p.I464M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV53525082; called by muse, mutect2, varscan2
- ATRNL1 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as rs782432237, COSV61799560; called by muse, mutect2
- AURKC | c.442G>T p.E148* (on ENST00000302804 / NM_001015878.2; = p.E114* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100248927, COSV57140611; called by muse, mutect2, varscan2
- AVPR1A | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV54545893; called by muse, mutect2, varscan2
- AXIN1 | c.1765A>G p.S589G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51984528; called by muse, mutect2, varscan2
- BACH2 | c.2330C>A p.P777H | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as COSV57587339; called by muse, mutect2, varscan2
- BCAN | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 118/229 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1228691023, COSV61255872; called by muse, mutect2, varscan2
- BCAS3 | c.215-1G>A p.X72_splice | Splice Site (SNP) | VAF 12/45 reads (27%) | catalogued as COSV66771142; called by muse, mutect2, varscan2
- BCL11A | c.1895C>G p.S632C (on ENST00000335712 / NM_001365609.1; = p.S666C on NM_018014.4) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59626246; called by muse, mutect2, varscan2
- BCL6 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.253); catalogued as COSV51650587, COSV51652457; called by muse, mutect2, varscan2
- BDP1 | c.3334G>A p.G1112S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV62429784; called by muse, mutect2, varscan2
- BHMT | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57153799, COSV57155603; called by muse, mutect2, varscan2
- BICC1 | c.2341G>T p.V781L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.672); catalogued as COSV54062591; called by muse, mutect2, varscan2
- BLOC1S2 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100705076; called by muse, mutect2, varscan2
- BMS1 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65733166; called by muse, mutect2, varscan2
- BRD4 | c.1629G>C p.K543N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV54583621; called by muse, mutect2
- BRINP3 | c.1270C>A p.H424N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV66516763; called by muse, mutect2, varscan2
- BUB1 | c.668C>G p.S223* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV57061958; called by muse, mutect2, varscan2
- C20orf194 | c.2592G>A p.M864I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV52693024; called by muse, mutect2, varscan2
- C2orf16 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.639); catalogued as COSV68645541; called by muse, mutect2, varscan2
- C2orf16 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.774); catalogued as COSV68645545, COSV68645863; called by muse, mutect2, varscan2
- C3orf70 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV58586905; called by muse, mutect2, varscan2
- C6 | c.2605G>T p.D869Y | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs115220610, COSV54707056; called by mutect2, varscan2
- C6 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54707063; called by muse, mutect2, varscan2
- CABP1 | c.983G>A p.R328Q (on ENST00000316803 / NM_001033677.1; = p.R125Q on NM_004276.5) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.445); catalogued as rs866526568, COSV56457899, COSV56459072; called by muse, mutect2, varscan2
- CACNA1G | c.2221G>T p.D741Y | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61721933; called by muse, mutect2, varscan2
- CACNG2 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55633281; called by muse, mutect2, varscan2
- CAMKK1 | c.623A>T p.H208L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50114647; called by muse, mutect2, varscan2
- CAMKV | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); catalogued as COSV56554485; called by muse, mutect2, varscan2
- CAMTA1 | c.4438A>G p.S1480G | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV57887322; called by muse, mutect2, varscan2
- CAPN11 | c.964T>A p.W322R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67236736; called by muse, mutect2, varscan2
- CAPN9 | c.953+2T>A p.X318_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV55231627; called by muse, mutect2, varscan2
- CASQ1 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV63623979; called by muse, mutect2, varscan2
- CATSPERE | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV63676758; called by muse, mutect2, varscan2
- CBL | c.2680G>T p.E894* | Nonsense Mutation (SNP) | VAF 127/319 reads (40%) | catalogued as COSV50631635, COSV50677442; called by mutect2, varscan2
- CCDC6 | c.1180A>T p.N394Y | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as COSV54055495; called by muse, mutect2, varscan2
- CCDC78 | c.1182C>A p.D394E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV53495500; called by muse, mutect2, varscan2
- CCDC87 | c.2510A>T p.H837L | Missense Mutation (SNP) | VAF 102/308 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV59578604; called by muse, mutect2, varscan2
- CCND1 | c.74A>C p.D25A | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV57119875; called by muse, mutect2, varscan2
- CCR2 | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV52747969; called by muse, mutect2, varscan2
- CD300A | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV60409696; called by muse, mutect2, varscan2
- CD33 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV51800539; called by muse, mutect2, varscan2
- CD33 | c.928C>A p.H310N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV51800558; called by muse, mutect2, varscan2
- CD5 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as COSV61718028; called by muse, mutect2, varscan2
- CD83 | c.178A>T p.M60L | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64787648; called by muse, mutect2, varscan2
- CD99L2 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV57986695; called by muse, mutect2
- CDCA7L | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs201734057, COSV62258479; called by muse, mutect2, varscan2
- CDH10 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV52574133; called by muse, mutect2, varscan2
- CDH12 | c.1518A>G p.I506M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV66393601; called by muse, mutect2, varscan2
- CDH2 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52274334; called by muse, mutect2, varscan2
- CDK13 | c.4078G>C p.A1360P | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.502); catalogued as rs1288031998, COSV51697493; called by muse, mutect2, varscan2
- CDKN2A | c.155T>G p.M52R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV58688565, COSV58689863, COSV58725322; called by muse, mutect2, varscan2
- CDYL | c.652G>T p.E218* (on ENST00000328908 / NM_001368125.1; = p.E164* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV59358767; called by muse, mutect2, varscan2
- CENPE | c.4270C>G p.L1424V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.76); catalogued as COSV54377949; called by muse, mutect2, varscan2
- CEP152 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as rs1210137540, COSV100359009; called by muse, mutect2, varscan2
- CEP152 | c.2082A>T p.L694F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100359010; called by muse, mutect2, varscan2
- CFAP251 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 20/137 reads (15%) | catalogued as COSV56608924; called by muse, mutect2, varscan2
- CFAP46 | c.6630G>A p.M2210I | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.107); catalogued as COSV54150221; called by muse, mutect2, varscan2
- CFAP70 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60281722; called by muse, mutect2, varscan2
- CFDP1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52207911; called by mutect2, varscan2
- CHD6 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58554239; called by muse, mutect2, varscan2
- CHD8 | c.6769G>C p.D2257H (on ENST00000646647 / NM_001170629.2; = p.D1978H on NM_020920.4) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV63036576; called by muse, mutect2, varscan2
- CHMP4B | c.223T>C p.Y75H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV99459921; called by muse, mutect2, varscan2
- CHRD | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 204/382 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52606248, COSV99200426; called by muse, mutect2, varscan2
- CHRNA1 | c.1037G>T p.R346L (on ENST00000261007 / NM_001039523.3; = p.R321L on NM_000079.4) | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV53682061, COSV53683259; called by muse, mutect2, varscan2
- CHRNA4 | c.1188C>G p.S396R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV64718765, COSV64720317; called by muse, mutect2
- CIC | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV50552047, COSV50555799; called by muse, mutect2, varscan2
- CLEC16A | c.1633A>G p.R545G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs757795232, COSV68498540; called by muse, mutect2, varscan2
- CLEC4F | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV55478593; called by muse, mutect2, varscan2
- CLK4 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60317999; called by muse, mutect2, varscan2
- CLTCL1 | c.4417G>C p.E1473Q | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV54226713; called by muse, mutect2, varscan2
- CMPK2 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV56774177; called by muse, mutect2, varscan2
- CNGA2 | c.1357C>A p.R453S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as rs755787323, COSV61703700, COSV61705041; called by muse, mutect2, varscan2
- CNTN1 | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as rs759677391, COSV61637404; called by muse, mutect2, varscan2
- COBL | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54340899; called by muse, mutect2, varscan2
- COL11A1 | c.1295C>G p.A432G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as COSV62176078; called by muse, mutect2, varscan2
- COL14A1 | c.3886C>G p.P1296A | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV52849671, COSV52857235; called by muse, mutect2, varscan2
- COL3A1 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV58584162; called by muse, mutect2, varscan2
- COL4A6 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100564661; called by mutect2, varscan2
- COL4A6 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100564662; called by mutect2, varscan2
- COL5A1 | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs1208939443, COSV65666644; called by muse, mutect2, varscan2
- COL9A1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV61830105; called by muse, mutect2, varscan2
- COL9A2 | c.421del p.D141Tfs*42 | Frame Shift Del (DEL) | VAF 37/100 reads (37%) | catalogued as COSV65607297; called by mutect2, pindel, varscan2
- COLEC11 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV52592230; called by muse, mutect2, varscan2
- COLQ | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV67524277, COSV67525299; called by muse, mutect2, varscan2
- CORO1C | c.321A>G p.V107= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV54594675; called by muse, mutect2, varscan2
- CPSF2 | c.1043A>T p.D348V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV54097470; called by muse, mutect2, varscan2
- CREB5 | c.1078C>T p.Q360* (on ENST00000357727 / NM_182898.4; = p.Q353* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV63218452, COSV63219666; called by muse, mutect2
- CRNKL1 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66105594; called by muse, mutect2, varscan2
- CSF1R | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV53830990; called by muse, mutect2, varscan2
- CSMD2 | c.8155C>G p.P2719A | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV53890177, COSV53891470, COSV53901887; called by muse, mutect2
- CSMD3 | c.7726C>G p.P2576A (on ENST00000297405 / NM_001363185.1; = p.P2472A on NM_052900.3) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.403); catalogued as COSV52129343; called by muse, mutect2, varscan2
- CSMD3 | c.2281C>G p.L761V (on ENST00000297405 / NM_001363185.1; = p.L657V on NM_052900.3) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52129362, COSV99828094, COSV99841759; called by muse, mutect2, varscan2
- CSNK1G1 | c.690del p.R231Efs*7 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as COSV100274178; called by mutect2, pindel, varscan2
- CTNNA3 | c.2006A>T p.E669V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs377166040; called by muse, mutect2, varscan2
- CTNND2 | c.2787C>A p.I929= | Splice Region (SNP) | VAF 13/69 reads (19%) | catalogued as COSV58872981; called by muse, mutect2, varscan2
- CUL5 | c.1451G>A p.G484D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV67608399; called by muse, mutect2, varscan2
- CXCR2 | c.862C>A p.R288S | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.898); catalogued as COSV59280046, COSV59281534; called by muse, mutect2, varscan2
- CXCR4 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 105/376 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV54010898; called by muse, mutect2, varscan2
- CYP1A1 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65696780; called by muse, varscan2
- CYP21A2 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100926464; called by mutect2, varscan2
- CYP24A1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV53773292; called by muse, mutect2, varscan2
- CYP2B6 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs572134005, COSV57842876; called by muse, mutect2, varscan2
- CYP2C18 | c.231G>T p.L77F | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs755901390, COSV53670548; called by muse, mutect2, varscan2
- CYP2C18 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV53670557; called by muse, mutect2, varscan2
- CYP3A7 | c.970C>A p.H324N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as COSV60480298, COSV60480876; called by muse, mutect2, varscan2
- CYP4X1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.059); catalogued as COSV64149986; called by muse, mutect2, varscan2
- DACT1 | c.1025T>A p.I342N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60019860; called by muse, mutect2, varscan2
- DBX2 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV60336702, COSV60339821; called by muse, mutect2, varscan2
- DCAF12L2 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 36/134 reads (27%) | catalogued as COSV63580787; called by muse, mutect2, varscan2
- DCAF8 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as COSV58783101; called by muse, mutect2, varscan2
- DCDC1 | c.2113A>T p.T705S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.423); catalogued as COSV60836810; called by muse, mutect2, varscan2
- DDIAS | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV61271692; called by muse, mutect2, varscan2
- DDX17 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV53251377, COSV53255915; called by muse, mutect2, varscan2
- DEGS1 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60378802; called by muse, mutect2, varscan2
- DHX37 | c.1304G>T p.R435M | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58132843; called by muse, mutect2, varscan2
- DHX57 | c.1016A>C p.D339A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV54883341; called by muse, mutect2, varscan2
- DIS3L2 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV56050451; called by muse, mutect2, varscan2
- DMBT1 | c.4949G>T p.R1650L (on ENST00000338354 / NM_001377530.1; = p.R893L on NM_004406.3) | Missense Mutation (SNP) | VAF 83/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775509248, COSV57537673, COSV57538240; called by muse, mutect2, varscan2
- DMRT2 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV52401204; called by muse, mutect2, varscan2
- DNAAF3 | c.1333G>T p.A445S (on ENST00000524407 / NM_001256715.2; = p.A492S on NM_178837.4) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as rs768592462, COSV61275914; called by muse, mutect2, varscan2
- DNAH1 | c.11254G>T p.D3752Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV70227241; called by muse, mutect2, varscan2
- DNAH11 | c.5501G>A p.R1834H | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs750430725, COSV60945433; ClinVar: uncertain significance; called by muse, mutect2
- DNAJC6 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54771615; called by muse, mutect2, varscan2
- DNHD1 | c.11593A>T p.S3865C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54432134; called by muse, mutect2, varscan2
- DOCK2 | c.2733C>G p.I911M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV56947788; called by muse, mutect2
- DPF3 | c.476A>G p.E159G | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV63499267; called by muse, mutect2, varscan2
- DPP4 | c.1180T>A p.C394S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV62105728; called by muse, mutect2
- DRD3 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55679227; called by muse, mutect2, varscan2
- DRD3 | c.134T>A p.F45Y | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55679238; called by muse, mutect2
- DRD5 | c.398T>A p.V133D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV58577168; called by muse, mutect2, varscan2
- DSCAML1 | c.883C>A p.Q295K (on ENST00000321322; = p.Q235K on NM_020693.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV58385010; called by muse, mutect2, varscan2
- DSEL | c.1753C>T p.L585F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59490137; called by muse, mutect2
- DST | c.16051C>G p.Q5351E (on ENST00000361203 / NM_001374722.1; = p.Q2939E on NM_015548.5) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); catalogued as COSV55003459; called by muse, mutect2, varscan2
- DTNA | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV51995122, COSV52002591; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1138G>A p.D380N (on ENST00000361735 / NM_015935.5; = p.D294N on NM_014955.3) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as COSV62282670; called by muse, mutect2, varscan2
- EFCAB13 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58946595; called by muse, mutect2
- EIF4ENIF1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57515123; called by muse, mutect2, varscan2
- EIF4G1 | c.3371C>G p.S1124* (on ENST00000346169 / NM_198241.3; = p.S929* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 10/210 reads (5%) | catalogued as COSV59989805; called by muse, mutect2
- EIF5B | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV56811692; called by muse, mutect2, varscan2
- ELMO2 | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV51681845; called by muse, mutect2, varscan2
- ELOA2 | c.1396T>A p.S466T | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV55295144; called by muse, mutect2, varscan2
- ELP2 | c.1253G>T p.W418L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60849461; called by muse, mutect2, varscan2
- EML4 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100581489, COSV59295170; called by muse, mutect2, varscan2
- ENOX1 | c.699G>T p.R233S | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54891298; called by muse, mutect2
- ENTPD1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV64600588; called by muse, mutect2, varscan2
- EPB41L4A | c.1544G>T p.W515L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54864692; called by muse, mutect2, varscan2
- EPHA10 | c.1952T>C p.L651P | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57621932; called by muse, mutect2, varscan2
- EPHA3 | c.2882C>G p.P961R | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV60698074, COSV60722530; called by muse, mutect2
- EPHA5 | c.844T>C p.W282R | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56635862; called by muse, varscan2
- EPHA6 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV67563797, COSV67593476; called by muse, mutect2, varscan2
- EPHA7 | c.936T>G p.C312W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65178959; called by muse, mutect2, varscan2
- EPHB1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV67656151; called by muse, mutect2
- ERCC6 | c.3007G>C p.E1003Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63388556; called by muse, mutect2, varscan2
- EXOC3L1 | c.2005C>G p.L669V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV52045494; called by muse, mutect2, varscan2
- EXOC7 | c.502G>T p.V168L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV58740054; called by muse, mutect2, varscan2
- EYA1 | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV58158917; called by muse, mutect2, varscan2
- EZH2 | c.1490G>A p.R497Q (on ENST00000460911 / NM_001203247.2; = p.R502Q on NM_004456.5) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1263153853, COSV57448811, COSV99052998; called by muse, mutect2, varscan2
- F8 | c.5488G>A p.E1830K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); catalogued as COSV64270634; called by muse, mutect2, varscan2
- FADS6 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100043868, COSV100044310; called by muse, varscan2
- FAM13C | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53245076; called by muse, mutect2, varscan2
- FAM160A2 | c.1875G>T p.E625D (on ENST00000449352 / NM_001098794.2; = p.E639D on NM_032127.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56410205; called by muse, mutect2, varscan2
- FAM71A | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54234966; called by muse, mutect2
- FAM83C | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.436); catalogued as COSV65582399; called by muse, mutect2
- FANCM | c.2375C>G p.S792* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV57498428; called by muse, mutect2, varscan2
- FAT3 | c.6764A>G p.K2255R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV53088164; called by muse, mutect2, varscan2
- FBN1 | c.7789C>T p.L2597F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.996); catalogued as CD1312141, COSV57312065; called by muse, mutect2
- FBN1 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV57312074; called by muse, mutect2, varscan2
- FBN2 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV52499778; called by muse, mutect2, varscan2
- FBXL7 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs548322966, COSV61642962, COSV61648367; called by muse, mutect2, varscan2
- FCGR1A | c.856C>G p.P286A | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV64985389; called by muse, mutect2, varscan2
- FCHO1 | c.2078C>A p.A693D | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV53181389; called by muse, mutect2, varscan2
- FCRL4 | c.1247C>A p.S416* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as COSV54860767; called by muse, varscan2
- FCRL5 | c.2318G>A p.C773Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.09); catalogued as COSV62512796; called by muse, mutect2, varscan2
- FHL1 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61780171; called by muse, mutect2, varscan2
- FIG4 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57785826; called by muse, mutect2, varscan2
- FLACC1 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53782685; called by muse, mutect2, varscan2
- FLG | c.5824C>A p.H1942N | Missense Mutation (SNP) | VAF 256/685 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV64238598; called by muse, varscan2
- FLG | c.2219G>T p.R740L | Missense Mutation (SNP) | VAF 90/752 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV100910374, COSV64238603; called by muse, mutect2, varscan2
- FLNB | c.4388G>C p.R1463P | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV55873516; called by muse, mutect2, varscan2
- FLT1 | c.3752C>A p.A1251D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1342649833, COSV56721515; called by muse, mutect2, varscan2
- FLT1 | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56721532; called by muse, mutect2, varscan2
- FLT3 | c.2957C>A p.P986Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); catalogued as COSV54047766, COSV54049596; called by muse, mutect2, varscan2
- FMO1 | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV61445023; called by muse, mutect2, varscan2
- FOLR3 | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV61529954; called by muse, mutect2, varscan2
- FOXE3 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM163143, COSV100624042, COSV58632486; called by muse, mutect2
- FPR2 | c.92T>A p.V31E | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV60672229; called by muse, mutect2, varscan2
- FPR2 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV60672236; called by muse, mutect2, varscan2
- FPR3 | c.145T>A p.W49R | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59328707; called by muse, mutect2, varscan2
- FRMD3 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); catalogued as COSV58456649; called by muse, mutect2, varscan2
- FSCN3 | c.512_514del p.A171del | In Frame Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs1226954046; called by pindel, varscan2
- G3BP1 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV62365773; called by muse, mutect2, varscan2
- GABRR1 | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65619001, COSV65619281; called by muse, mutect2, varscan2
- GAD1 | c.1567A>T p.R523W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64025215; called by muse, mutect2, varscan2
- GALNT10 | c.1799T>G p.F600C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV51722100; called by muse, varscan2
- GARS1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66828055; called by muse, mutect2, varscan2
- GAS2L3 | c.1421T>C p.L474S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs893113700, COSV57156464; called by muse, mutect2, varscan2
- GCK | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56267484; called by muse, mutect2, varscan2
- GEMIN7 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99541651; called by muse, mutect2, varscan2
- GGH | c.834A>G p.E278= | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as rs778610598, COSV52649627; called by muse, mutect2, varscan2
- GJA5 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54783114, COSV99605717; called by muse, mutect2, varscan2
- GLO1 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV64905071; called by muse, mutect2, varscan2
- GLYAT | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.964); catalogued as COSV53538273, COSV53538715; called by muse, mutect2, varscan2
- GLYAT | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53538730, COSV99557501; called by muse, mutect2
- GML | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV55276610; called by muse, mutect2, varscan2
- GMPS | c.319A>G p.M107V | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV55808414; called by muse, mutect2, varscan2
- GOLGA1 | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV63024138, COSV63024143; called by muse, mutect2, varscan2
- GOLGB1 | c.2204A>G p.N735S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1402761486, COSV61463097; called by muse, mutect2, varscan2
- GOLT1A | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV55331435; called by muse, varscan2
- GPR158 | c.1624A>C p.I542L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV66266935; called by muse, mutect2, varscan2
- GPR158 | c.2681C>A p.P894Q | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV66266938; called by muse, mutect2, varscan2
- GPR39 | c.1283T>A p.L428H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.365); catalogued as COSV61416002; called by muse, mutect2, varscan2
- GPR4 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100546922, COSV100546982, COSV59916428; called by muse, mutect2, varscan2
- GPRIN1 | c.1601A>T p.K534M | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV56135950; called by muse, mutect2, varscan2
- GRIK3 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901906, COSV66136884; called by muse, mutect2
- GRIN2B | c.3159C>A p.D1053E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.109); catalogued as COSV74205137, COSV74206667; called by muse, mutect2, varscan2
- GRIN3A | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV62451861; called by muse, mutect2, varscan2
- GTPBP1 | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV53283748; called by muse, mutect2
- H2AZ2 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56062148, COSV56062905; called by muse, mutect2, varscan2
- H2BC10 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV59952767, COSV59953351; called by muse, mutect2, varscan2
- H3C10 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV60797337; called by muse, mutect2
- HABP4 | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64514676; called by muse, mutect2, varscan2
- HCK | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776412545, COSV52941097; called by muse, mutect2, varscan2
- HDC | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV99984198; called by muse, mutect2, varscan2
- HDC | c.1123C>G p.Q375E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV51068709; called by muse, mutect2, varscan2
- HDC | c.181A>T p.I61F | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); catalogued as COSV51068718; called by muse, mutect2, varscan2
- HELQ | c.2999A>G p.K1000R | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV55024464; called by muse, mutect2, varscan2
- HGD | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52196674; called by muse, mutect2
- HK1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.01); catalogued as COSV64350504; called by muse, mutect2, varscan2
- HK2 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as rs763634644, COSV51873897; called by muse, mutect2, varscan2
- HMCN1 | c.6391C>T p.P2131S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54885346; called by muse, mutect2
- HNRNPA1 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52935986; called by muse, mutect2, varscan2
- HNRNPH1 | c.1037C>G p.S346* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV61485148; called by muse, mutect2
- HNRNPLL | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV55367110; called by muse, mutect2, varscan2
- HOXA1 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56065578; called by muse, mutect2, varscan2
- HOXC13 | c.844A>G p.S282G | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV54498300, COSV54498893; called by muse, mutect2, varscan2
- HPS5 | c.2095G>A p.E699K (on ENST00000349215 / NM_181507.2; = p.E585K on NM_007216.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.092); catalogued as COSV61687231; called by muse, mutect2, varscan2
- HPS5 | c.1663G>A p.E555K (on ENST00000349215 / NM_181507.2; = p.E441K on NM_007216.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV61687238; called by muse, mutect2, varscan2
- HPS5 | c.825-1G>A p.X275_splice (on ENST00000349215 / NM_181507.2; = p.X161_splice on NM_007216.4) | Splice Site (SNP) | VAF 4/31 reads (13%) | catalogued as COSV62538952; called by muse, mutect2, varscan2
- HRH4 | c.94G>T p.G32* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as COSV56927621; called by muse, mutect2, varscan2
- HSP90B1 | c.2258C>G p.A753G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV55354462; called by mutect2, varscan2
- HSPG2 | c.1634A>G p.D545G | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV65930100; called by muse, mutect2, varscan2
- IFI16 | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55532197; called by muse, mutect2, varscan2
- IFT172 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs777168931, COSV53131271; called by muse, mutect2, varscan2
- IGDCC4 | c.3463C>A p.P1155T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.1); catalogued as COSV61535916; called by muse, mutect2, varscan2
- IGF2R | c.6399G>T p.Q2133H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV63482165; called by muse, mutect2, varscan2
- IGHM | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.737); catalogued as rs369232248; called by muse, mutect2, varscan2
- IGHV5-51 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs782344647; called by muse, mutect2, varscan2
- IGKV1-6 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779529366; called by muse, mutect2, varscan2
- IHH | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs1559178825, COSV55392917; called by muse, mutect2, varscan2
- IKBKB | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV60596275; called by muse, mutect2, varscan2
- IL1A | c.110A>G p.H37R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV54519110; called by muse, mutect2, varscan2
- IL4R | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748811310, COSV50139604; called by muse, mutect2, varscan2
- INMT | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs1334310876, COSV50000512; called by muse, mutect2, varscan2
- INO80B | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs115610738, COSV51968607; called by muse, mutect2, varscan2
- INPP4B | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as COSV53715649, COSV53747965; called by muse, mutect2, varscan2
- INTS5 | c.1523T>C p.V508A | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV57950742; called by muse, mutect2, varscan2
- IRF9 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60702865; called by muse, mutect2, varscan2
- IRGQ | c.1750G>T p.G584C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV60670348; called by muse, mutect2, varscan2
- IRS1 | c.2193C>G p.D731E | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59334589; called by muse, mutect2
- IRS4 | c.1714_1715insT p.G572Vfs*32 | Frame Shift Ins (INS) | VAF 48/206 reads (23%) | catalogued as COSV100929644; called by mutect2, pindel, varscan2
- IRX2 | c.1085C>G p.S362* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV57410212; called by muse, mutect2
- ISG20 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs748762729, COSV60143504; called by muse, mutect2, varscan2
- ITGA8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65226342; called by muse, mutect2, varscan2
- ITGAD | c.1543C>A p.H515N | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV66757152; called by muse, mutect2, varscan2
- ITGAE | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV53990712, COSV99560144; called by muse, mutect2, varscan2
- ITPR2 | c.7400-1G>C p.X2467_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV67266495; called by muse, mutect2, varscan2
- JAK1 | c.1488G>C p.K496N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61088663; called by muse, mutect2, varscan2
- JAM2 | c.878C>A p.T293K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100468918, COSV57256059; called by muse, mutect2, varscan2
- KALRN | c.1865T>A p.L622Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53756406; called by muse, mutect2, varscan2
- KALRN | c.7374G>A p.M2458I (on ENST00000360013 / NM_001024660.4; = p.M761I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.899); catalogued as COSV52252038; called by muse, mutect2, varscan2
- KALRN | c.8227C>T p.L2743F (on ENST00000360013 / NM_001024660.4; = p.L1046F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV52252055; called by muse, mutect2, varscan2
- KBTBD6 | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs542001637, COSV65271033; called by muse, mutect2, varscan2
- KCNA2 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60369435; called by muse, mutect2, varscan2
- KCNB2 | c.552G>C p.E184D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV73049374, COSV73050465; called by muse, mutect2, varscan2
- KCNJ6 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV55710847; called by muse, mutect2, varscan2
- KCNN1 | c.808A>T p.T270S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV55836962, COSV55837615, COSV55838227; called by muse, mutect2
- KCNS3 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV58405863; called by muse, mutect2, varscan2
- KCNU1 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.211); catalogued as COSV67754125; called by muse, mutect2, varscan2
- KCNV1 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV52085116; called by muse, mutect2, varscan2
- KHDRBS1 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV56981415; called by muse, mutect2, varscan2
- KHNYN | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.607); catalogued as COSV52159230; called by muse, mutect2, varscan2
- KIAA1549L | c.1707T>A p.D569E (on ENST00000321505; = p.D866E on NM_012194.3) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.012); catalogued as rs767994861, COSV55770912; called by muse, mutect2, varscan2
- KIAA1755 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99642397; called by muse, mutect2, varscan2
- KIDINS220 | c.3457G>C p.G1153R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as COSV56751374; called by muse, mutect2
- KIF18B | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV59271702; called by muse, mutect2
- KLB | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV57300654; called by muse, mutect2, varscan2
- KLF6 | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51494080, COSV99434913; called by muse, mutect2, varscan2
- KLHL1 | c.311A>C p.Q104P | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.046); catalogued as COSV64768630; called by muse, mutect2, varscan2
- KLHL14 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63830724; called by muse, mutect2, varscan2
- KLHL20 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.259); catalogued as COSV52940789; called by muse, mutect2, varscan2
- KLHL28 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV61887642; called by muse, mutect2
- KLHL4 | c.450G>C p.M150I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64140042; called by muse, mutect2, varscan2
- KLHL4 | c.2149C>A p.L717I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV64140051; called by muse, mutect2, varscan2
- KMT2A | c.4804C>A p.L1602I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV63283401; called by muse, mutect2
- KMT2D | c.6421G>T p.G2141W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56421354; called by muse, varscan2
- KPRP | c.1489A>T p.S497C | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64221216; called by muse, mutect2, varscan2
- KRT2 | c.1078G>T p.A360S | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59009561, COSV59011448; called by muse, mutect2, varscan2
- KRT2 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59009570; called by muse, mutect2, varscan2
- KRT8 | c.1360C>G p.R454G | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as CM057883, COSV53176380; called by muse, mutect2, varscan2
- KRT82 | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV99233775; called by muse, mutect2, varscan2
- KRTAP10-11 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV58177331; called by muse, mutect2, varscan2
- KRTAP10-8 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV58166066; called by muse, mutect2, varscan2
- KRTAP13-2 | c.198C>G p.C66W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV67761906; called by muse, mutect2, varscan2
- KRTAP15-1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV61877159; called by muse, mutect2, varscan2
- LAD1 | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV66212214; called by muse, mutect2
- LAMA5 | c.7872G>T p.E2624D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53355332, COSV99442205; called by muse, mutect2, varscan2
- LAMP5 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.446); catalogued as COSV55715465; called by muse, mutect2, varscan2
- LARGE1 | c.2065G>C p.D689H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV61659215, COSV61668355; called by muse, mutect2, varscan2
- LCK | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV60739086; called by muse, mutect2, varscan2
- LCT | c.2162C>A p.S721* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV51545713, COSV51552532; called by muse, mutect2
- LDB1 | c.230G>T p.R77L (on ENST00000425280 / NM_001321612.2; = p.R41L on NM_003893.5) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63288832; called by muse, mutect2, varscan2
- LENG8 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV58726604; called by muse, mutect2, varscan2
- LGR5 | c.1751G>A p.R584K | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV57003526; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.264G>T p.R88S | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.216); catalogued as COSV53276488; called by muse, mutect2
- LIPI | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 92/145 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV60709310; called by muse, mutect2, varscan2
- LLGL2 | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV99390146; called by muse, mutect2, varscan2
- LLGL2 | c.2108G>T p.R703L | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51344156; called by muse, mutect2, varscan2
- LRFN5 | c.21T>A p.Y7* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV53247615; called by muse, mutect2, varscan2
- LRP1B | c.1983G>C p.W661C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67197711; called by muse, mutect2
- LRP2 | c.2735A>T p.Q912L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV55545368; called by muse, mutect2, varscan2
- LRRC31 | c.279G>C p.L93F | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52980020; called by muse, mutect2, varscan2
- LRRC32 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV52632062, COSV52634683; called by muse, mutect2, varscan2
- LRRC55 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV73006380, COSV73006796, COSV73006817; called by muse, mutect2, varscan2
- LRRC66 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.666); catalogued as COSV58632560; called by muse, mutect2, varscan2
- LTBP1 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs1453602920, COSV63182584; called by muse, mutect2
- LTN1 | c.4876-1G>T p.X1626_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV63733266; called by muse, mutect2
- LVRN | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752119554, COSV63496613; called by muse, mutect2, varscan2
- LYPD6B | c.479G>C p.R160T (on ENST00000409029 / NM_001317004.1; = p.R184T on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV54518026; called by muse, mutect2, varscan2
- LYSMD2 | c.368T>C p.L123S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV51056712; called by muse, mutect2, varscan2
- LZTS2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs761998754, COSV64651221; called by muse, mutect2, varscan2
- MAG | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV62699474, COSV62700883; called by muse, mutect2, varscan2
- MAGEA11 | c.226A>T p.S76C | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV60754328; called by muse, mutect2, varscan2
- MAGEB6 | c.1008G>T p.L336F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV66872026; called by muse, mutect2, varscan2
- MAGEE2 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV64897464; called by muse, mutect2, varscan2
- MAP3K19 | c.912G>C p.K304N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV59637313; called by muse, mutect2
- MAP3K2 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61293432; called by muse, mutect2, varscan2
- MAP3K9 | c.973A>T p.M325L | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67120436; called by muse, mutect2, varscan2
- MAPK7 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as rs748692208, COSV55189757; called by muse, mutect2, varscan2
- MARCHF4 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV56103662; called by muse, mutect2, varscan2
- MARK1 | c.1610G>C p.G537A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV65066171; called by muse, mutect2, varscan2
- MASP2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.213); catalogued as rs779641842, COSV53569337; called by muse, mutect2, varscan2
- MAZ | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs748661675, COSV99361325; called by mutect2, varscan2
- MED12L | c.1748C>T p.S583F | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs761281341, COSV56372256; called by muse, mutect2, varscan2
- MEF2D | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs767074542, COSV61727358; called by muse, mutect2, varscan2
- MEFV | c.1724C>G p.S575* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV54819627, COSV54825044; called by muse, mutect2, varscan2
- MEX3B | c.270A>T p.K90N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61663053; called by muse, mutect2, varscan2
- MFSD8 | c.1094A>T p.Q365L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV56550699; called by muse, mutect2, varscan2
- MIB1 | c.716G>A p.G239D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.986); catalogued as COSV55088709; called by muse, mutect2
- MKI67 | c.6988A>T p.K2330* | Nonsense Mutation (SNP) | VAF 121/427 reads (28%) | catalogued as COSV64073232; called by muse, mutect2, varscan2
- MMP16 | c.737A>T p.H246L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54155557, COSV99687724; called by muse, mutect2, varscan2
- MNAT1 | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV54187905; called by muse, mutect2, varscan2
- MOB4 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV52095302; called by muse, mutect2, varscan2
- MRPS5 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55533073; called by muse, mutect2, varscan2
- MSH4 | c.1499T>A p.I500K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV54198560; called by muse, mutect2, varscan2
- MSH4 | c.2048T>A p.M683K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV54198584; called by muse, mutect2, varscan2
- MTNR1B | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV57065749, COSV99925430; called by muse, mutect2, varscan2
- MTNR1B | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57065762; called by muse, mutect2, varscan2
- MTUS2 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV70914864; called by muse, mutect2, varscan2
- MUC16 | c.42061C>A p.H14021N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV66690495; called by muse, mutect2, varscan2
- MUC16 | c.15373G>T p.E5125* | Nonsense Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV67453122, COSV67464076; called by muse, mutect2, varscan2
- MUC5B | c.13267G>A p.E4423K | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV71590577; called by muse, mutect2, varscan2
- MYBPC3 | c.1010C>G p.A337G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV57024737; called by muse, mutect2, varscan2
- MYCBP2 | c.3876G>T p.W1292C (on ENST00000357337; = p.W1330C on NM_015057.5) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62012803; called by muse, mutect2, varscan2
- MYH4 | c.585C>A p.Y195* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV55114038; called by muse, mutect2, varscan2
- MYLIP | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV62766489; called by muse, mutect2, varscan2
- MYO18B | c.3540C>G p.I1180M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59128727; called by muse, mutect2, varscan2
- N4BP2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs533904341, COSV54700185; called by muse, mutect2, varscan2
- NAALADL1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60523236; called by muse, mutect2, varscan2
- NABP2 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99907589; called by muse, mutect2, varscan2
- NAV3 | c.989A>T p.K330M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57067819; called by muse, mutect2, varscan2
- NAV3 | c.1350del p.A451Lfs*41 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | catalogued as rs35015855; called by mutect2, pindel, varscan2
- NAV3 | c.5618C>A p.T1873N (on ENST00000397909 / NM_001024383.2; = p.T1851N on NM_014903.6) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as COSV57067838; called by muse, mutect2, varscan2
- NBEA | c.8404G>T p.G2802C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV59767932; called by muse, mutect2, varscan2
- NCAM1 | c.1395C>G p.I465M (on ENST00000316851 / NM_181351.5; = p.I455M on NM_000615.7) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV57512918; called by muse, mutect2, varscan2
- NCKAP1L | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53204580; called by muse, mutect2, varscan2
- NCOA1 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV56040832; called by muse, mutect2, varscan2
- NCOA6 | c.5234C>T p.S1745F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1167772569, COSV62862077; called by muse, mutect2, varscan2
- NDST2 | c.1723C>G p.Q575E | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1171949997, COSV55213326; called by muse, mutect2, varscan2
- NDST4 | c.2488A>G p.M830V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs752863165, COSV52112404; called by muse, mutect2
- NDUFAF7 | c.379A>G p.R127G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV50017052; called by muse, mutect2
- NDUFS8 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV50288094; called by muse, mutect2, varscan2
- NECAB3 | c.432C>G p.F144L | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55775207; called by muse, mutect2
- NEK9 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV53129872; called by muse, mutect2, varscan2
- NELFCD | c.1648A>G p.I550V (on ENST00000602795; = p.I532V on NM_198976.4) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as rs1015884580, COSV53882720; called by muse, mutect2, varscan2
- NELL2 | c.1493T>A p.L498* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV61571201; called by muse, mutect2, varscan2
- NEUROD6 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.913); catalogued as rs777808758, COSV51770617; called by muse, mutect2, varscan2
- NEUROG2 | c.322C>A p.R108S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV57637021; called by muse, mutect2, varscan2
- NEUROG3 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140128333, CM115180; called by mutect2, varscan2
- NGDN | c.563G>C p.R188P | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV68142071; called by muse, mutect2, varscan2
- NHEJ1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV59428010; called by muse, mutect2, varscan2
- NKTR | c.3709G>T p.A1237S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV51770299; called by muse, mutect2, varscan2
- NKX2-5 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100234940, COSV61298589; called by muse, mutect2, varscan2
- NLGN1 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.272); catalogued as COSV64324308; called by muse, mutect2, varscan2
- NMT2 | c.95C>G p.T32R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV65381462, COSV65381783; called by muse, mutect2, varscan2
- NOP14 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as COSV58624397; called by muse, mutect2
- NOS2 | c.2083C>A p.P695T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.848); catalogued as rs1161590401, COSV58222477, COSV58227999; called by muse, mutect2, varscan2
- NOVA1 | c.805G>C p.G269R | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57473772; called by muse, mutect2, varscan2
- NOVA2 | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1171132494, COSV54356335; called by muse, varscan2
- NPAS3 | c.1843C>G p.R615G (on ENST00000356141 / NM_001164749.2; = p.R583G on NM_022123.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.06); catalogued as COSV100639869, COSV60825596; called by muse, mutect2, varscan2
- NPSR1 | c.1073A>T p.E358V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV62198081; called by muse, mutect2, varscan2
- NPY2R | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1405446935, COSV61527561; called by muse, mutect2, varscan2
- NR1H4 | c.1276C>T p.L426F (on ENST00000551379 / NM_001206993.2; = p.L412F on NM_005123.4) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51849822, COSV51850320; called by muse, mutect2, varscan2
- NR2E1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV64561655, COSV64562372; called by muse, mutect2, varscan2
- NR4A1 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54480581; called by muse, mutect2, varscan2
- NR5A2 | c.784G>T p.G262C (on ENST00000367362 / NM_205860.3; = p.G216C on NM_003822.5) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99371418; called by muse, mutect2, varscan2
- NR5A2 | c.785G>T p.G262V (on ENST00000367362 / NM_205860.3; = p.G216V on NM_003822.5) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV52654381, COSV99371420; called by muse, mutect2, varscan2
- NRCAM | c.3052T>A p.L1018I (on ENST00000379028 / NM_001371124.1; = p.L1002I on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV61032925; called by muse, mutect2, varscan2
- NRF1 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56210831, COSV56211308; called by muse, mutect2, varscan2
- NRP2 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV55925026; called by muse, mutect2, varscan2
- NRXN2 | c.4870G>T p.G1624C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV55449659, COSV99633600; called by muse, mutect2, varscan2
- NUCKS1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV63347811; called by muse, mutect2
- NUP210L | c.2165A>C p.Q722P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV55143647; called by muse, mutect2, varscan2
- NYAP2 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56000773; called by muse, mutect2, varscan2
- OBSCN | c.20985C>G p.I6995M | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62208918; called by muse, mutect2, varscan2
- OIT3 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV61825442; called by muse, mutect2, varscan2
- OLAH | c.188G>T p.R63I (on ENST00000378228 / NM_001039702.3; = p.R116I on NM_018324.3) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65491813; called by muse, mutect2, varscan2
- OPLAH | c.2764G>C p.D922H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70677385, COSV70677459; called by muse, mutect2, varscan2
- OR13C3 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV66165692, COSV66166418; called by muse, mutect2, varscan2
- OR13G1 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV62943353, COSV62943685; called by muse, mutect2, varscan2
- OR1L4 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV52339955; called by muse, mutect2, varscan2
- OR1N2 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV65460366; called by muse, mutect2, varscan2
- OR2M2 | c.124A>T p.N42Y | Missense Mutation (SNP) | VAF 124/241 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62897972; called by muse, mutect2, varscan2
- OR2T27 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV61281183; called by mutect2, varscan2
- OR2T34 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1458126700, COSV60899952; called by muse, mutect2, varscan2
- OR2V2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.674); catalogued as COSV60314628; called by muse, mutect2, varscan2
- OR2V2 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV60314942; called by muse, mutect2, varscan2
- OR2W3 | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV64456332; called by muse, mutect2, varscan2
- OR2Y1 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV57136268; called by muse, mutect2, varscan2
- OR4E2 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as COSV100330130; called by muse, mutect2, varscan2
- OR4M1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs548222329, COSV100271360; called by muse, mutect2, varscan2
- OR4M2 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100221254, COSV60306757; called by mutect2, varscan2
- OR4S2 | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV56746211; called by muse, mutect2, varscan2
- OR51B6 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.764); catalogued as COSV66512477; called by muse, mutect2, varscan2
- OR51E1 | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV67809524, COSV67809965; called by muse, mutect2, varscan2
- OR56B4 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV57204178; called by muse, mutect2, varscan2
- OR5B21 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as rs907530877, COSV64481686; called by muse, mutect2, varscan2
- OR5B21 | c.39G>C p.L13F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV64481691; called by muse, mutect2, varscan2
- OR5M1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73202002; called by muse, mutect2, varscan2
- OR6C2 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as COSV59515727; called by muse, mutect2, varscan2
- OR6C4 | c.154del p.H52Tfs*16 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | catalogued as COSV67793392; called by mutect2, pindel, varscan2
- OR6K3 | c.301C>A p.L101I (on ENST00000368146; = p.L85I on NM_001005327.2) | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV63745407; called by muse, mutect2, varscan2
- OR9K2 | c.245C>A p.T82K (on ENST00000305377; = p.T60K on NM_001005243.1) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59531553; called by muse, mutect2, varscan2
- OSBPL11 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV56172947; called by muse, mutect2, varscan2
- OSBPL3 | c.108A>T p.E36D | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57654265; called by muse, mutect2, varscan2
- OTOA | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV53751135; called by muse, mutect2, varscan2
- OTOP1 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56391653; called by muse, mutect2, varscan2
- PABPC3 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879732; called by muse, varscan2
- PADI2 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as COSV64945455; called by muse, mutect2, varscan2
- PATZ1 | c.1969G>C p.E657Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56742999, COSV56743116; called by muse, mutect2
- PAX3 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.104); catalogued as COSV60586923; called by muse, mutect2
- PCDH1 | c.3582C>G p.F1194L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV54612078; called by muse, mutect2, varscan2
- PCDH10 | c.1699C>G p.Q567E | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV52088403, COSV52089728; called by muse, mutect2, varscan2
- PCDHA4 | c.2309T>C p.M770T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV63539736; called by muse, mutect2, varscan2
- PCDHAC1 | c.2402G>A p.R801K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.017); catalogued as COSV53841059; called by muse, mutect2, varscan2
- PCDHB4 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV52020391, COSV52026805; called by muse, mutect2, varscan2
- PCDHB5 | c.941A>C p.Y314S | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV50648233, COSV50659224; called by muse, mutect2, varscan2
- PCDHB5 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as COSV50648249; called by muse, mutect2, varscan2
- PCDHB6 | c.641T>A p.L214Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV50691738; called by muse, mutect2, varscan2
- PCDHB8 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.574); catalogued as COSV50757227; called by muse, mutect2, varscan2
- PCDHB8 | c.1856G>T p.W619L | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV50757230; called by muse, mutect2, varscan2
- PCDHB9 | c.994A>T p.T332S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as COSV53376494; called by muse, mutect2, varscan2
- PCDHGA12 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV52746627; called by muse, mutect2, varscan2
- PCDHGB3 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53915342; called by muse, mutect2, varscan2
- PCDHGB6 | c.1202A>T p.Y401F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV53915374; called by muse, mutect2, varscan2
- PCDHGB6 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV53915382; called by muse, mutect2, varscan2
- PCID2 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55813171; called by muse, mutect2
- PCK1 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs747837917, COSV60126763, COSV60131546; called by muse, mutect2, varscan2
- PCSK4 | c.1417A>G p.R473G | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56298591, COSV99960865; called by muse, mutect2, varscan2
- PDE1C | c.1976T>A p.L659* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV58506540; called by muse, mutect2, varscan2
- PDE1C | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs1181737020, COSV58506466; called by muse, mutect2, varscan2
- PDE6A | c.1622C>A p.A541D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV54925504; called by muse, mutect2, varscan2
- PDE7B | c.1235A>T p.Q412L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV57494329; called by muse, mutect2
- PDZD8 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1265351801, COSV53689084; called by muse, mutect2, varscan2
- PGAM5 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100453105, COSV58201797; called by muse, mutect2
- PGBD2 | c.90G>T p.M30I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV61399809; called by muse, mutect2, varscan2
- PGK2 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV59163193; called by muse, mutect2, varscan2
- PHKA1 | c.3598A>G p.M1200V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1556200720, COSV59803411; called by muse, mutect2, varscan2
- PHLDB2 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV67309138; called by muse, mutect2, varscan2
- PIGT | c.1601C>G p.T534S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54125497; called by muse, mutect2, varscan2
- PIGZ | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99433910; called by muse, mutect2, varscan2
- PIKFYVE | c.5917G>T p.V1973F | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52238540; called by muse, mutect2, varscan2
- PJA2 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV63272162; called by muse, mutect2, varscan2
- PKD1 | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV51912638; called by muse, mutect2, varscan2
- PKHD1L1 | c.5438G>A p.S1813N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs768349010, COSV65739585; called by muse, mutect2, varscan2
- PKN2 | c.2422A>G p.M808V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV65142225; called by muse, mutect2, varscan2
- PLA2G15 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV54722593; called by muse, mutect2, varscan2
- PLAAT5 | c.397G>T p.G133* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV57136461; called by muse, mutect2, varscan2
- PLAGL2 | c.969G>C p.M323I | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.119); catalogued as COSV55787772; called by muse, mutect2, varscan2
- PLCB1 | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1364886743, COSV62042906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCH1 | c.1783A>T p.M595L (on ENST00000340059 / NM_001130960.2; = p.M607L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV58190546; called by muse, mutect2, varscan2
- PLCL1 | c.2855C>T p.P952L | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV70823351; called by muse, mutect2, varscan2
- PLCXD3 | c.774A>C p.K258N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV60606445; called by muse, mutect2, varscan2
- PLEKHA4 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV54361809; called by muse, mutect2, varscan2
- PLEKHG2 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV52679926; called by muse, mutect2, varscan2
- PLS1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61833114; called by muse, mutect2
- PLXNA1 | c.3827G>T p.R1276L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.8); catalogued as COSV52523440, COSV52530311; called by muse, mutect2, varscan2
- PLXNA1 | c.4376A>G p.E1459G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52523450; called by muse, mutect2, varscan2
- PLXNA2 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65438532, COSV65443494; called by muse, mutect2, varscan2
- PLXND1 | c.3156G>T p.E1052D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV100140137; called by muse, mutect2
- PNKP | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV55586924, COSV55587606; called by muse, mutect2, varscan2
- PNRC2 | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as COSV57623104; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1382A>T p.D461V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV57963555; called by muse, mutect2, varscan2
- POLR1F | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as COSV55998005, COSV55998716; called by muse, mutect2, varscan2
- POLR2D | c.229A>T p.R77* | Nonsense Mutation (SNP) | VAF 22/156 reads (14%) | catalogued as COSV55758190; called by muse, mutect2, varscan2
- POLR3B | c.2237A>G p.Y746C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1228870515, COSV57276841; called by muse, mutect2
- POM121 | c.1417G>A p.D473N (on ENST00000434423; = p.D208N on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs1434954026, COSV57513059; called by muse, mutect2, varscan2
- POM121L12 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV68692478; called by muse, mutect2, varscan2
- POU2F2 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.081); catalogued as COSV60760729; called by muse, mutect2, varscan2
- PPM1F | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV99601606; called by muse, mutect2
- PPP1R16B | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 89/354 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV55375308, COSV55385993; called by muse, mutect2, varscan2
- PPP2R1A | c.986G>T p.C329F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV59043138; called by muse, mutect2, varscan2
- PRAME | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.131); catalogued as COSV67161208; called by muse, mutect2, varscan2
- PRDM16 | c.2224G>T p.D742Y | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54583045; called by muse, mutect2, varscan2
- PRDM4 | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV57304959; called by muse, mutect2, varscan2
- PRDM5 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as COSV53357408; called by muse, mutect2, varscan2
- PRKCB | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV57770822; called by muse, mutect2, varscan2
- PRKD2 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52185179, COSV52187662, COSV52188578; called by muse, mutect2, varscan2
- PRNP | c.517A>C p.N173H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV65173534; called by muse, mutect2, varscan2
- PROS1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV62397966; called by muse, mutect2
- PRSS1 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756821075, COSV61191523; called by muse, mutect2, varscan2
- PSG2 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100283624; called by muse, mutect2, varscan2
- PSG2 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757071267, COSV100283626; called by muse, mutect2, varscan2
- PTCH1 | c.768G>C p.W256C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467038, COSV59467715; called by muse, mutect2, varscan2
- PTGER2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1301996899, COSV99817604; called by muse, mutect2
- PTGFRN | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.43); catalogued as COSV67798014; called by muse, mutect2, varscan2
- PTPN14 | c.2641C>T p.R881W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as rs533330548, COSV65282228; called by muse, mutect2, varscan2
- PTPN14 | c.1418A>T p.N473I | Missense Mutation (SNP) | VAF 133/283 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65282232; called by muse, mutect2, varscan2
- PTPRR | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV51727245; called by muse, mutect2, varscan2
- PTPRU | c.1997G>T p.G666V | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV60523720, COSV60524038; called by muse, mutect2, varscan2
- PTPRZ1 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV66432680, COSV66446883; called by muse, mutect2, varscan2
- PUM1 | c.2592-2A>C p.X864_splice | Splice Site (SNP) | VAF 22/60 reads (37%) | catalogued as COSV57082951; called by muse, mutect2, varscan2
- PYGM | c.1828-1G>T p.X610_splice | Splice Site (SNP) | VAF 43/145 reads (30%) | catalogued as COSV51215319; called by muse, mutect2, varscan2
- PYGO2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.585); catalogued as rs773508848, COSV63756720; called by muse, mutect2, varscan2
- QTRT2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV55559228; called by muse, mutect2, varscan2
- RAB6D | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV72151635; called by mutect2, varscan2
- RAG2 | c.885C>A p.N295K | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.764); catalogued as COSV57556844; called by muse, mutect2, varscan2
- RAPGEF2 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV52425855; called by muse, mutect2, varscan2
- RASA3 | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV61865073; called by muse, mutect2, varscan2
- RBM19 | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1247065509, COSV55689339; called by muse, mutect2, varscan2
- RBM39 | c.1291A>G p.M431V (on ENST00000253363 / NM_001323424.2; = p.M425V on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV53614394; called by muse, mutect2, varscan2
- RBM47 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55931723; called by muse, mutect2, varscan2
- REEP3 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53423630; called by muse, mutect2, varscan2
- RFX1 | c.1851G>A p.E617= | Splice Region (SNP) | VAF 31/74 reads (42%) | catalogued as COSV54328421; called by muse, mutect2, varscan2
- RGS12 | c.3033G>T p.K1011N | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58749815; called by muse, mutect2, varscan2
- RHCG | c.1285T>A p.C429S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV51515086; called by muse, mutect2, varscan2
- RIMS2 | c.2867C>T p.P956L (on ENST00000666250 / NM_001348490.2; = p.P764L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV51662389; called by muse, mutect2
- RIN1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV60925797; called by muse, mutect2, varscan2
- RNF213 | c.1285G>C p.D429H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60620918; called by muse, mutect2, varscan2
- RNGTT | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV55647614; called by muse, mutect2, varscan2
- ROCK1 | c.2676G>T p.L892F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67694967; called by muse, mutect2, varscan2
- RPIA | c.594C>G p.F198L | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV52168547, COSV52169569; called by muse, mutect2, varscan2
- RPRD1B | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65032452; called by muse, mutect2, varscan2
- RPRD2 | c.1471A>G p.S491G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV64819064; called by muse, mutect2, varscan2
- RUNX1 | c.511G>A p.D171N (on ENST00000344691 / NM_001001890.3; = p.D198N on NM_001754.5) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as CM013280, CM1515470, COSV55868860, COSV55892672; called by muse, mutect2, varscan2
- RYR1 | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM054848, COSV62092259, COSV62108976; called by mutect2, varscan2
- RYR2 | c.3730A>G p.N1244D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV63671142; called by muse, mutect2, varscan2
- RYR3 | c.7126G>T p.D2376Y (on ENST00000389232; = p.D2377Y on NM_001036.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66781711, COSV66790652; called by muse, mutect2, varscan2
- S100PBP | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV63139848; called by muse, mutect2, varscan2
- SALL3 | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV73305866; called by muse, mutect2, varscan2
- SASH1 | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV66559780; called by muse, mutect2, varscan2
- SCLY | c.1300G>C p.E434Q (on ENST00000651534; = p.E426Q on NM_016510.7) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV54540577; called by muse, mutect2, varscan2
- SCN1A | c.126A>T p.K42N | Missense Mutation (SNP) | VAF 117/230 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as CD105519, COSV57663910; called by muse, mutect2, varscan2
- SCN2A | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV51832124; called by muse, mutect2, varscan2
- SCN2A | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV51835615; called by muse, mutect2
- SCOC | c.439A>G p.S147G (on ENST00000608372; = p.S110G on NM_032547.3) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58392702; called by muse, mutect2, varscan2
- SDK1 | c.3018G>C p.Q1006H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1301134090, COSV67360301; called by muse, mutect2, varscan2
- SDK2 | c.1411G>T p.G471W | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101168074, COSV101168677; called by muse, mutect2, varscan2
- SDR16C5 | c.809T>G p.L270W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV100373723, COSV58125799; called by muse, mutect2, varscan2
- SELP | c.2369C>T p.T790M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.373); catalogued as rs75278502; called by muse, mutect2
- SEMA3D | c.2177G>C p.S726T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as COSV52389632; called by muse, mutect2, varscan2
- SEMA5B | c.2958C>G p.S986R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.648); catalogued as COSV52093122; called by muse, mutect2, varscan2
- SEMG1 | c.433del p.D145Ifs*27 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as COSV54874341; called by mutect2, pindel, varscan2
- SENP7 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV58608272; called by muse, mutect2, varscan2
- SERPINA9 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV100099109, COSV54073583; called by muse, mutect2, varscan2
- SERPINB13 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.926); catalogued as rs369861529; called by muse, mutect2, varscan2
- SETBP1 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV56315918; called by muse, mutect2, varscan2
- SETDB1 | c.3364C>G p.Q1122E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV54978699; called by muse, mutect2, varscan2
- SH2D2A | c.1154T>G p.L385R | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63884551; called by muse, mutect2
- SH2D2A | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs992896140, COSV63884570; called by muse, varscan2
- SH3BP1 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.045); catalogued as COSV53216304; called by muse, mutect2, varscan2
- SH3BP4 | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV60642868; called by muse, mutect2, varscan2
- SH3BP4 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs866404069, COSV60642875; called by muse, mutect2, varscan2
- SHPRH | c.2937G>T p.Q979H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51606173; called by muse, mutect2, varscan2
- SIGLEC12 | c.1780C>A p.P594T (on ENST00000291707 / NM_053003.4; = p.P476T on NM_033329.2) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as COSV52460154; called by muse, mutect2, varscan2
- SIPA1 | c.2696G>T p.R899M | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV58014124; called by muse, mutect2, varscan2
- SIRT1 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99281930; called by muse, mutect2, varscan2
- SKIV2L | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 166/338 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV64810755; called by muse, mutect2, varscan2
- SLC14A2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV54907281; called by muse, mutect2, varscan2
- SLC22A6 | c.245C>A p.T82N | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.211); catalogued as rs1353606182, COSV64559950; called by muse, mutect2, varscan2
- SLC24A2 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs377522340; called by muse, mutect2, varscan2
- SLC25A2 | c.68G>A p.C23Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV53404421, COSV99508305; called by muse, mutect2, varscan2
- SLC25A2 | c.67T>A p.C23S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.549); catalogued as COSV99508309; called by muse, mutect2, varscan2
- SLC25A31 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55418026; called by muse, mutect2, varscan2
- SLC25A53 | c.444A>C p.Q148H | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.382); catalogued as COSV62458557; called by muse, mutect2, varscan2
- SLC25A6 | c.525G>C p.Q175H | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV67317577; called by muse, mutect2, varscan2
- SLC26A8 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV62884980; called by muse, mutect2, varscan2
- SLC28A3 | c.1272G>T p.M424I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV66152360; called by muse, mutect2, varscan2
- SLC32A1 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1473110302, COSV54146028; called by muse, mutect2, varscan2
- SLC33A1 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63946824; called by muse, mutect2, varscan2
- SLC38A10 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV55843620; called by muse, mutect2, varscan2
- SLC38A10 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs773661289, COSV55843634; called by muse, mutect2, varscan2
- SLC38A8 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55305256; called by muse, mutect2, varscan2
- SLC38A9 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.992); catalogued as rs1271201783, COSV59422341; called by muse, mutect2
- SLC3A1 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53221537; called by muse, mutect2, varscan2
- SLC3A2 | c.1525G>C p.V509L | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV58603031; called by muse, mutect2, varscan2
- SLC45A2 | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV56870291; called by muse, mutect2, varscan2
- SLC4A1 | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52258994; called by muse, mutect2, varscan2
- SLC4A1 | c.635C>T p.S212L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV52259006; called by muse, varscan2
- SLC5A7 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50889772; called by muse, mutect2, varscan2
- SLC6A15 | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99881258; called by muse, mutect2
- SLC7A6 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54718128; called by muse, mutect2, varscan2
- SLC9C2 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV100876952, COSV62944522; called by muse, mutect2
- SLIT1 | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as rs748707121, COSV56584912; called by muse, mutect2, varscan2
- SLITRK4 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV100567439; called by muse, mutect2, varscan2
- SLITRK4 | c.2487G>T p.E829D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100567440; called by muse, mutect2, varscan2
- SMURF2 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1555684658, COSV52313489; called by muse, mutect2, varscan2
- SNAP25 | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV54771199; called by muse, mutect2, varscan2
- SNTG1 | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV52431693; called by muse, mutect2, varscan2
- SNX27 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV64325848; called by muse, mutect2, varscan2
- SOGA3 | c.2374C>T p.L792F | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.837); catalogued as COSV64105579; called by muse, mutect2, varscan2
- SOS1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV67674316; called by muse, mutect2, varscan2
- SOX1 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs1486851542, COSV58378675; called by muse, mutect2
- SPACA3 | c.582-1G>T p.X194_splice | Splice Site (SNP) | VAF 27/75 reads (36%) | catalogued as COSV52190659; called by muse, mutect2, varscan2
- SPAG5 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58800810; called by muse, mutect2, varscan2
- SPEF2 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56795442; called by muse, mutect2, varscan2
- SPEF2 | c.4217G>T p.S1406I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57427953; called by muse, mutect2, varscan2
- SPON2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV52054549; called by muse, mutect2, varscan2
- SPZ1 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV57062649; called by muse, mutect2
- SRCAP | c.3169G>T p.G1057W | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99350766; called by muse, mutect2, varscan2
- SRCAP | c.3170G>T p.G1057V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99350767; called by muse, mutect2, varscan2
- SRGAP1 | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as rs549866334, COSV61895544; called by muse, mutect2, varscan2
- SRGAP3 | c.889del p.E297Kfs*75 | Frame Shift Del (DEL) | VAF 27/142 reads (19%) | catalogued as COSV64533554; called by mutect2, pindel, varscan2
- SSTR3 | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1237771491, COSV60728838; called by muse, mutect2, varscan2
- ST8SIA3 | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | PolyPhen benign (0.022); catalogued as rs1363377732, COSV60653609; called by muse, mutect2, varscan2
- STK11IP | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as COSV55246655; called by muse, mutect2, varscan2
- SUOX | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as CD052509, COSV56267315; called by muse, mutect2, varscan2
- SUSD2 | c.782+2T>G p.X261_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV64203172; called by muse, mutect2, varscan2
- SUSD6 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1212049077, COSV61364839; called by muse, mutect2
- SYT11 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.62); catalogued as COSV64173846; called by muse, mutect2, varscan2
- TANGO6 | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55762112; called by muse, mutect2, varscan2
- TAP2 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV66487631; called by muse, mutect2, varscan2
- TARS2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV64694796; called by muse, mutect2, varscan2
- TBC1D31 | c.881A>C p.Q294P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.327); catalogued as COSV54864579; called by muse, mutect2, varscan2
- TBC1D8B | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52176900; called by muse, mutect2, varscan2
- TBL1XR1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV61789771; called by muse, mutect2, varscan2
- TBX21 | c.1344C>A p.F448L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV51595306; called by muse, mutect2, varscan2
- TCEA2 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58657383, COSV58659720; called by muse, mutect2
- TCHH | c.1996G>C p.E666Q | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV64273642; called by muse, mutect2, varscan2
- TCHHL1 | c.2231C>A p.S744* | Nonsense Mutation (SNP) | VAF 23/195 reads (12%) | catalogued as COSV64285146; called by muse, mutect2, varscan2
- TCHHL1 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 168/337 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64285151; called by muse, mutect2, varscan2
- TCOF1 | c.567G>A p.G189= | Splice Region (SNP) | VAF 19/65 reads (29%) | catalogued as COSV60346784; called by muse, mutect2, varscan2
- TDGF1 | c.36-1G>C p.X12_splice | Splice Site (SNP) | VAF 18/82 reads (22%) | catalogued as COSV56125359; called by muse, mutect2, varscan2
- TENM4 | c.4835A>G p.Y1612C | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53615662; called by muse, mutect2, varscan2
- TET1 | c.4219A>G p.T1407A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV65383034, COSV65390518; called by muse, mutect2, varscan2
- TEX9 | c.395+1G>A p.X132_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV61877318; called by muse, mutect2
- TH | c.234G>T p.K78N (on ENST00000381178 / NM_199292.3; = p.K47N on NM_000360.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV60766920; called by mutect2, varscan2
- THBS2 | c.1916C>A p.A639D | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64677629; called by muse, mutect2, varscan2
- THNSL2 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV59082272; called by muse, mutect2, varscan2
- THSD7A | c.3049A>T p.R1017* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV70261914; called by muse, mutect2, varscan2
- TIAM2 | c.2654C>A p.P885Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.785); catalogued as COSV59691082; called by muse, mutect2, varscan2
- TLE3 | c.2240G>A p.C747Y | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167453; called by muse, mutect2, varscan2
- TLR9 | c.1285G>T p.G429* | Nonsense Mutation (SNP) | VAF 49/193 reads (25%) | catalogued as COSV62345941, COSV62347095; called by muse, mutect2, varscan2
- TMEM132A | c.1347G>T p.Q449H (on ENST00000453848 / NM_178031.3; = p.Q450H on NM_017870.4) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs760853384, COSV50002687; called by muse, mutect2, varscan2
- TMEM18 | c.318G>C p.M106I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV55243529; called by muse, mutect2, varscan2
- TMEM200A | c.1088T>C p.M363T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51650455; called by muse, varscan2
- TMTC1 | c.1041G>T p.E347D (on ENST00000539277 / NM_001193451.2; = p.E239D on NM_175861.3) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV55477469; called by muse, mutect2, varscan2
- TNIP3 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV50246353; called by muse, mutect2, varscan2
- TNNI2 | c.451A>T p.K151* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV53289017; called by muse, mutect2, varscan2
- TNS2 | c.890T>C p.M297T (on ENST00000314250 / NM_170754.4; = p.M307T on NM_015319.2) | Missense Mutation (SNP) | VAF 228/428 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs376985824; called by muse, mutect2, varscan2
- TNXB | c.6079G>A p.E2027K (on ENST00000647633; = p.E1780K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV64475564; called by muse, mutect2, varscan2
- TP73 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs530648280, COSV60699425; called by muse, mutect2, varscan2
- TRAV24 | c.57C>G p.C19W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs372848781; called by muse, mutect2, varscan2
- TRBV20-1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs201903499; called by muse, mutect2, varscan2
- TREH | c.528C>G p.D176E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50619967; called by muse, mutect2, varscan2
- TREX1 | c.464G>C p.S155T (on ENST00000625293 / NM_033629.6; = p.S145T on NM_007248.5) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); catalogued as COSV99604122; called by muse, mutect2, varscan2
- TRHDE | c.948G>T p.W316C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53837367; called by muse, mutect2, varscan2
- TRIM37 | c.1517A>G p.N506S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs77807605, COSV51882335; called by muse, mutect2, varscan2
- TRPC4 | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV58993843; called by muse, mutect2, varscan2
- TRPC6 | c.592C>A p.Q198K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV60251938; called by muse, mutect2, varscan2
- TRPS1 | c.3549G>T p.E1183D (on ENST00000220888 / NM_001330599.2; = p.E1196D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); catalogued as COSV55230940; called by muse, mutect2, varscan2
433 further variants in this file (133 protein-altering or splice-affecting, 269 silent, 31 other) are not listed here.
